Gene-level copy-number profile of tumor specimen TCGA-A6-2678-01A from TCGA case TCGA-A6-2678, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Transverse colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 43.9 years (16,030 days).
Specimen TCGA-A6-2678-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.2874d5e3-cec1-4481-84f9-e0f511e33754.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A6-2678-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3796047f-f2ef-4888-82a1-de1d04454c31

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 12,072; copy number 2: 44,692; copy number 3: 2,884; copy number 4: 29; copy number 5: 143.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A6-2678-01A-01D-1549-01): tumor purity 0.82, ploidy 1.84, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 143 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:129,922,863–131,836,532, 132 genes, copy number 5 (broad region; genes not listed).
- chr16:51,054,728–51,525,157, 11 genes, copy number 5 (within-gene range 2–5): AC027688.2, AC009166.3, SOD1P2, SALL1, AC009166.1, AC087564.1, AC009166.2, AC137494.1, AC137527.1, UNGP1, AC007344.1.

Autosomal genes at a single copy (total copy number 1): 12,072. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
